Somatic mutation profile of tumor specimen TCGA-22-0940-01A (aliquot TCGA-22-0940-01A-01W-0782-08) from TCGA case TCGA-22-0940, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.9 years (26,272 days).
Specimen TCGA-22-0940-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dc6bb0f-2f79-4200-93f3-c6471c0e6949.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-0940-11A (Solid Tissue Normal), aliquot TCGA-22-0940-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b952172a-d64a-49e8-8eb9-13c805b2a0c5

The open-access MAF lists 235 somatic variants for this specimen: 172 protein-altering or splice-affecting, 56 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 56, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 5, Intron 4, RNA 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4055T>C p.L1352P (on ENST00000303395 / NM_001202435.3; = p.L1341P on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794726821, CM1511244, COSV100320487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3461G>T p.R1154L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99067430, COSV99285825; called by muse, mutect2, varscan2
- ABCB5 | c.693G>T p.L231F | Missense Mutation (SNP) | VAF 159/341 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.139); catalogued as COSV99328416; called by muse, mutect2, varscan2
- ABCC11 | c.3499G>C p.G1167R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV100750769; called by muse, mutect2, varscan2
- ACOX1 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV99503595; called by muse, mutect2, varscan2
- ACSS3 | c.1721C>G p.S574* | Nonsense Mutation (SNP) | VAF 57/319 reads (18%) | catalogued as COSV99698855; called by muse, varscan2
- ACTR5 | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99710039; called by muse, mutect2, varscan2
- ADAMTS16 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV56996280, COSV57006645; called by muse, mutect2, varscan2
- ADAMTS19 | c.1328G>T p.R443M | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50735197, COSV99178846; called by muse, mutect2, varscan2
- ADAMTS20 | c.4252G>A p.D1418N | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as COSV101166264, COSV67127896; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4867G>A p.D1623N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs750437275, COSV99718908; called by muse, mutect2, varscan2
- ADD1 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs768137427, COSV53270893; called by muse, mutect2, varscan2
- AGAP4 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as rs782270678, COSV101432663; called by muse, mutect2
- ALOX15 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99541422; called by muse, mutect2, varscan2
- AMBN | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100534356; called by muse, mutect2, varscan2
- ANK2 | c.8398G>A p.D2800N | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.361); catalogued as COSV100001729; called by muse, mutect2, varscan2
- ANKRD30A | c.452T>C p.I151T (on ENST00000611781; = p.I95T on NM_052997.2) | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100653568, COSV64617938; called by muse, mutect2
- ANO4 | c.2585G>C p.R862P (on ENST00000392977 / NM_001286615.2; = p.R827P on NM_178826.4) | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152915; called by muse, mutect2
- APBB1 | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100194042; called by muse, mutect2, varscan2
- ARHGAP30 | c.1412G>C p.G471A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100920276; called by muse, mutect2, varscan2
- ARL6IP6 | c.583T>C p.F195L | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV100424012; called by muse, mutect2, varscan2
- ASIC5 | c.1505T>A p.I502K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101611138; called by muse, mutect2, varscan2
- ATP7B | c.3565T>A p.C1189S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99666456; called by muse, mutect2, varscan2
- BIN1 | c.823G>A p.G275R (on ENST00000316724 / NM_001320642.1; = p.G244R on NM_004305.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as rs771506242, COSV99388046; called by muse, mutect2, varscan2
- BMPER | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99779635; called by muse, mutect2, varscan2
- C9orf153 | c.79T>A p.Y27N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100188656; called by muse, mutect2, varscan2
- CADPS | c.3693C>G p.D1231E | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); catalogued as COSV99338388; called by muse, mutect2, varscan2
- CAV1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV61953769; called by muse, mutect2, varscan2
- CDC20B | c.1410T>A p.D470E | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV99696921; called by muse, mutect2
- CDH6 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99419244; called by muse, mutect2, varscan2
- CENPE | c.3340G>C p.E1114Q | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV99477981; called by muse, mutect2, varscan2
- CFTR | c.2816A>T p.H939L | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as CM962472, CX993898, COSV99136293; called by muse, mutect2, varscan2
- CHRM2 | c.319A>C p.S107R | Missense Mutation (SNP) | VAF 55/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100281317; called by muse, mutect2, varscan2
- CHURC1 | c.256+1G>A p.X86_splice | Splice Site (SNP) | VAF 46/255 reads (18%) | catalogued as rs779160320, COSV100767452; called by muse, mutect2, varscan2
- CLCA1 | c.1873A>T p.S625C | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs557341333, COSV99322370; called by muse, mutect2, varscan2
- CLEC4F | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV99713744; called by muse, mutect2, varscan2
- CLRN2 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.994); catalogued as COSV101566458; called by muse, mutect2, varscan2
- CNOT1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as COSV100409320; called by muse, mutect2, varscan2
- COL17A1 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100793172; called by muse, mutect2
- COL22A1 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 102/524 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100278564; called by muse, mutect2, varscan2
- CORIN | c.2767G>T p.D923Y | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99903656; called by muse, mutect2, varscan2
- CORIN | c.1217A>G p.K406R | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99903658; called by muse, mutect2, varscan2
- CRB1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100957886; called by muse, mutect2, varscan2
- CSMD1 | c.2317C>A p.P773T (on ENST00000520002; = p.P772T on NM_033225.6) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100148096; called by muse, mutect2, varscan2
- DACH2 | c.1222C>A p.H408N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV100913247; called by muse, mutect2, varscan2
- DDX3X | c.1805G>A p.R602Q (on ENST00000399959; = p.R603Q on NM_001356.5) | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101302338; called by muse, mutect2, varscan2
- DIRAS2 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV101005860; called by muse, mutect2, varscan2
- DMP1 | c.496A>G p.R166G | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99218736; called by muse, mutect2
- DMXL2 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99196381; called by muse, mutect2, varscan2
- DNAAF4 | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs750814401, COSV100336736; called by muse, mutect2, varscan2
- DPEP3 | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV99262714; called by muse, mutect2
- DPP4 | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV62108854; called by muse, mutect2
- DPYSL5 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs139539355, COSV56509634; called by muse, mutect2, varscan2
- ENPP3 | c.1483A>T p.I495F | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV100717311; called by muse, mutect2, varscan2
- ERCC6L2 | c.2087A>G p.K696R | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1300174166, COSV99998624; called by muse, mutect2, varscan2
- FBLN7 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV100485556; called by muse, mutect2, varscan2
- FGA | c.1002G>A p.W334* | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | catalogued as CM001690, COSV100120387; called by muse, mutect2, varscan2
- FRAS1 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV99352166; called by muse, mutect2, varscan2
- GARNL3 | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 61/265 reads (23%) | catalogued as COSV59223405; called by muse, mutect2, varscan2
- GCNT4 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV100466488; called by muse, mutect2, varscan2
- GPAA1 | c.1544T>C p.L515P | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554764276, COSV100731143; called by muse, mutect2, varscan2
- GRXCR1 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV67674524; called by muse, mutect2, varscan2
- HACE1 | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99493686; called by muse, mutect2, varscan2
- HASPIN | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV53994350, COSV99560971; called by muse, mutect2, varscan2
- HEPACAM2 | c.890C>T p.P297L (on ENST00000394468 / NM_001039372.4; = p.P285L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100506569; called by muse, mutect2, varscan2
- HHLA2 | c.915G>C p.M305I | Missense Mutation (SNP) | VAF 29/430 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100755348, COSV100755394; called by muse, mutect2
- ILF3 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs137952515; called by muse, mutect2, varscan2
- JAM3 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 67/410 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.58); catalogued as COSV100138184; called by muse, mutect2, varscan2
- KCNA5 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99363909; called by muse, mutect2, varscan2
- KIN | c.528A>T p.Q176H | Missense Mutation (SNP) | VAF 135/953 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101092574; called by muse, mutect2, varscan2
- KIR2DL1 | c.371-1G>T p.X124_splice | Splice Site (SNP) | VAF 270/1357 reads (20%) | catalogued as COSV52407583; called by muse, mutect2
- KRT13 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.241); catalogued as COSV99877369; called by muse, mutect2, varscan2
- KRT74 | c.1178G>C p.G393A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977533; called by muse, varscan2
- LARP7 | c.833A>G p.K278R | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.997); catalogued as COSV100135153; called by mutect2, varscan2
- LCN2 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs749080993, COSV52981780, COSV99478201; called by muse, mutect2, varscan2
- LMOD2 | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101505448; called by muse, mutect2, varscan2
- LPL | c.1242C>A p.Y414* | Nonsense Mutation (SNP) | VAF 38/278 reads (14%) | catalogued as COSV100255602; called by muse, mutect2, varscan2
- LRP1B | c.11132-2A>T p.X3711_splice | Splice Site (SNP) | VAF 17/97 reads (18%) | catalogued as COSV101257251; called by muse, mutect2, varscan2
- LYZ | c.47T>A p.V16D | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99720125; called by muse, mutect2, varscan2
- MAGEB6 | c.923G>A p.W308* | Nonsense Mutation (SNP) | VAF 94/297 reads (32%) | catalogued as COSV100983746; called by muse, mutect2, varscan2
- MAGEC1 | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV99035707, COSV99595741; called by muse, mutect2, varscan2
- MAGEC1 | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV53572788, COSV99595743; called by muse, mutect2, varscan2
- MAGEL2 | c.3077C>G p.A1026G | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as COSV100045952; called by muse, mutect2, varscan2
- MTERF3 | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV99749777; called by muse, mutect2, varscan2
- MYH1 | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99875976; called by muse, mutect2, varscan2
- NAV3 | c.899A>C p.Q300P | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99891154; called by muse, mutect2, varscan2
- NRG4 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV101204859; called by muse, mutect2, varscan2
- NRK | c.1512G>C p.Q504H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99687846; called by muse, mutect2, varscan2
- OR14K1 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 274/703 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99315209; called by muse, mutect2, varscan2
- OR2G6 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as COSV100598173, COSV100598367; called by muse, mutect2, varscan2
- OR2K2 | c.314C>A p.A105D (on ENST00000374428; = p.A76D on NM_205859.2) | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100235307; called by muse, mutect2, varscan2
- OR5R1 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs201450981, COSV100393447, COSV56572037; called by muse, mutect2, varscan2
- OR6C1 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV101110513; called by muse, mutect2, varscan2
- OTOL1 | c.1175A>T p.Y392F | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.445); catalogued as COSV100020003; called by muse, mutect2, varscan2
- PCDH15 | c.5519G>A p.C1840Y | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1446034733, COSV100221287; called by muse, mutect2, varscan2
- PCDH15 | c.2673T>A p.S891R | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV100221291; called by muse, mutect2
- PCDHA13 | c.1554C>A p.Y518* | Nonsense Mutation (SNP) | VAF 39/238 reads (16%) | catalogued as COSV56528392, COSV99166429; called by muse, mutect2, varscan2
- PDE11A | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV100628862; called by muse, mutect2, varscan2
- PDK4 | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99138828; called by muse, mutect2, varscan2
- PLCL1 | c.2756C>A p.P919Q | Missense Mutation (SNP) | VAF 137/3081 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as COSV101406972; called by muse, mutect2
- PLXNB2 | c.4057C>G p.L1353V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834062; called by mutect2, varscan2
- POTEE | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 37/429 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV100387964, COSV100388294; called by muse, mutect2, varscan2
- PPFIA2 | c.2744C>A p.A915E | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1294674117, COSV100333478, COSV61041031; called by muse, mutect2, varscan2
- PXDN | c.2119G>T p.D707Y | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53235439, COSV99413551; called by muse, mutect2, varscan2
- PYGL | c.1544A>G p.D515G | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99368654; called by muse, mutect2, varscan2
- RELN | c.3257T>C p.V1086A | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100633774, COSV59004057; called by muse, mutect2, varscan2
- RFX6 | c.1486C>A p.L496M | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100263747, COSV60583497; called by muse, mutect2
- RIMS1 | c.177G>T p.R59S | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV53448727; called by muse, mutect2, varscan2
- RIPK4 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100204960; called by muse, mutect2, varscan2
- SCN11A | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs149681198, COSV100181606; called by muse, mutect2, varscan2
- SDC2 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100143446; called by muse, mutect2, varscan2
- SEC23A | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs541602739, COSV100305483; called by muse, mutect2, varscan2
- SEMA5A | c.2493G>T p.Q831H | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101228290; called by muse, mutect2, varscan2
- SEMA6D | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374815414, COSV100316985; called by muse, mutect2, varscan2
- SGK2 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763850331, COSV100414595, COSV100414657; called by muse, mutect2, varscan2
- SI | c.2879G>T p.C960F | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015605; called by muse, mutect2, varscan2
- SIDT2 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV99637703; called by muse, mutect2, varscan2
- SLC12A1 | c.536G>T p.W179L | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100372370; called by muse, mutect2, varscan2
- SLC12A5 | c.2637G>A p.M879I (on ENST00000454036 / NM_001134771.2; = p.M856I on NM_020708.5) | Missense Mutation (SNP) | VAF 88/714 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99716074; called by muse, mutect2, varscan2
- SLC18A2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs1363906830, COSV100041676; called by muse, mutect2, varscan2
- SLC24A5 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99981675; called by muse, mutect2, varscan2
- SLC45A2 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV56872959; called by muse, mutect2, varscan2
- SLC6A7 | c.1633C>A p.L545M | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as COSV100046624, COSV57940713; called by muse, mutect2
- SLITRK5 | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100280769; called by muse, mutect2, varscan2
- SMARCAD1 | c.2576T>C p.L859S | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100758932; called by muse, mutect2, varscan2
- SOS1 | c.3964G>A p.D1322N | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.355); catalogued as rs1167931335, COSV101216946; called by muse, mutect2, varscan2
- SPTAN1 | c.6691G>T p.G2231W | Missense Mutation (SNP) | VAF 171/690 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100823583; called by muse, mutect2, varscan2
- SRRM4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.445); catalogued as rs559217766, COSV57412500; called by muse, mutect2, varscan2
- TARBP1 | c.2794G>T p.A932S | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.412); catalogued as COSV99241645; called by muse, mutect2, varscan2
- TECPR2 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849996; called by muse, mutect2, varscan2
- TMEM225 | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100902764, COSV100902811; called by muse, mutect2, varscan2
- TNR | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV99689699; called by muse, mutect2, varscan2
- TOX | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100812741; called by muse, mutect2, varscan2
- TRIOBP | c.6893A>C p.K2298T (on ENST00000644935 / NM_001039141.3; = p.K585T on NM_007032.5) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100730862; called by muse, mutect2, varscan2
- TTLL9 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.81); PolyPhen probably damaging (1); catalogued as COSV100206763; called by muse, mutect2, varscan2
- TUBE1 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV100898283; called by muse, mutect2, varscan2
- TYR | c.466T>A p.Y156N | Missense Mutation (SNP) | VAF 91/444 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV99634231; called by muse, mutect2, varscan2
- UNC13C | c.2420C>A p.A807D | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52848675, COSV99517581; called by muse, mutect2, varscan2
- UNC5D | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV99775339; called by muse, mutect2, varscan2
- UPF1 | c.3257C>T p.P1086L (on ENST00000599848 / NM_001297549.2; = p.P1075L on NM_002911.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs767300705, COSV53200601, COSV99439599; called by mutect2, varscan2
- USP42 | c.3779G>A p.R1260K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374151941, COSV60361394; called by muse, mutect2, varscan2
- USP43 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV99556694; called by muse, mutect2, varscan2
- VPS13C | c.4694C>T p.S1565F (on ENST00000644861 / NM_020821.3; = p.S1522F on NM_017684.5) | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99828512; called by muse, mutect2, varscan2
- VWA3B | c.2993T>C p.M998T | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV101346034; called by muse, mutect2, varscan2
- WASHC5 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs753133551, COSV100572836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR17 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99707603; called by muse, mutect2, varscan2
- WDR17 | c.2369T>A p.F790Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.977); catalogued as COSV99707606; called by muse, mutect2, varscan2
- WDR36 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV101540803; called by muse, mutect2, varscan2
- WDR72 | c.1555C>G p.P519A | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100854486; called by muse, mutect2
- WNT9A | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs964011624, COSV99688243; called by muse, mutect2, varscan2
- YES1 | c.668A>C p.Y223S | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100099581; called by muse, mutect2, varscan2
- ZBTB44 | c.678A>T p.L226F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100777279; called by muse, mutect2, varscan2
- ZHX3 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs139157503, CM121424; called by muse, varscan2
- ZNF235 | c.2162G>T p.S721I | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99349470; called by muse, mutect2, varscan2
- ZNF257 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs372577233, COSV71309362; called by muse, mutect2, varscan2
- ADGRB2 | c.922+1G>A p.X308_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- CEP164 | c.893del p.G298Afs*31 | Frame Shift Del (DEL) | VAF 27/231 reads (12%) | called by mutect2, pindel, varscan2
- CHD7 | c.6297C>A p.D2099E | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.175); called by muse, mutect2
- CLIP4 | c.911C>A p.T304K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- CYP2C9 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 23/819 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.053); called by muse, mutect2
- CYTIP | c.988dup p.R330Pfs*40 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | called by pindel, varscan2
- DSE | c.1271del p.G424Dfs*61 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- ERGIC2 | c.444_447del p.F149Kfs*32 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | called by mutect2, pindel
- FLII | c.1987del p.Q663Rfs*4 | Frame Shift Del (DEL) | VAF 34/190 reads (18%) | called by mutect2, pindel
- GABPA | c.571A>C p.T191P | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- IGSF10 | c.6248C>T p.A2083V | Missense Mutation (SNP) | VAF 29/423 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.129); called by muse, mutect2
- OR2A5 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 36/715 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RAD18 | c.1222del p.D408Tfs*40 | Frame Shift Del (DEL) | VAF 27/141 reads (19%) | called by mutect2, pindel, varscan2
- RHEBL1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SYT17 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- TANC2 | c.2272_2276del p.M758Sfs*26 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by pindel, varscan2
- ADGRF5 | c.2850C>T p.G950= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs369402264, COSV51938125; called by muse, mutect2, varscan2
- ADGRL3 | c.2847G>A p.T949= (on ENST00000506720 / NM_001322402.2; = p.T881= on NM_015236.6) | Silent (SNP) | VAF 183/1264 reads (14%) | catalogued as rs750203484, COSV101547134; called by muse, mutect2, varscan2
- ALCAM | c.297T>C p.S99= | Silent (SNP) | VAF 35/334 reads (10%) | catalogued as COSV100064815; called by muse, mutect2, varscan2
- ANK3 | c.3048C>T p.A1016= (on ENST00000280772 / NM_001320874.2; = p.A150= on NM_001149.3) | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99780064; called by muse, mutect2, varscan2
- ANKRD6 | c.324G>T p.G108= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- BIRC3 | c.417A>T p.S139= | Silent (SNP) | VAF 74/287 reads (26%) | catalogued as COSV99679901; called by muse, mutect2, varscan2
- BRINP1 | c.1968G>A p.Q656= | Silent (SNP) | VAF 20/446 reads (4%) | called by muse, mutect2
- BRINP1 | c.501C>A p.L167= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as COSV99775498; called by muse, mutect2, varscan2
- CD19 | c.1386G>A p.E462= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as CD062127, COSV100218136; called by muse, mutect2
- CDHR1 | c.2454C>T p.L818= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100258890; called by muse, mutect2, varscan2
- CFAP251 | c.1350C>T p.S450= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as COSV99996135; called by muse, mutect2, varscan2
- CLRN2 | c.342C>A p.V114= | Silent (SNP) | VAF 84/293 reads (29%) | catalogued as COSV101566457; called by muse, mutect2, varscan2
- CMYA5 | c.7410G>A p.K2470= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV101484052, COSV101484416; called by muse, mutect2, varscan2
- COL26A1 | c.1270C>T p.L424= (on ENST00000313669 / NM_001278563.3; = p.L422= on NM_133457.4) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100561771; called by muse, mutect2, varscan2
- CSHL1 | c.654C>T p.G218= (on ENST00000309894 / NM_022581.3; = p.G124= on NM_001318.4) | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs200129211; called by muse, mutect2, varscan2
- CSMD3 | c.1056C>T p.T352= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV99834823; called by muse, mutect2, varscan2
- EZH1 | c.1059C>T p.P353= | Silent (SNP) | VAF 44/196 reads (22%) | catalogued as COSV101331366; called by muse, mutect2, varscan2
- FAM111B | c.1776G>A p.V592= | Silent (SNP) | VAF 29/186 reads (16%) | catalogued as rs202177353; called by muse, mutect2, varscan2
- GALNT17 | c.1713G>T p.V571= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100353990; called by muse, mutect2, varscan2
- GNPDA1 | c.204C>T p.T68= | Silent (SNP) | VAF 96/510 reads (19%) | catalogued as COSV100257557; called by muse, mutect2, varscan2
- IGKV3D-20 | c.91C>T p.L31= | Silent (SNP) | VAF 28/253 reads (11%) | catalogued as rs749001401; called by muse, mutect2, varscan2
- IGSF9B | c.1434G>A p.L478= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1266269394, COSV100317673; called by mutect2, varscan2
- ITGB3 | c.1986T>C p.R662= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV101457609; called by muse, mutect2, varscan2
- ITM2A | c.393C>A p.P131= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs764375775, COSV100964458; called by muse, mutect2, varscan2
- KDR | c.1050C>A p.I350= | Silent (SNP) | VAF 74/335 reads (22%) | catalogued as rs762537157, COSV99817768; called by muse, mutect2, varscan2
- MNDA | c.795C>T p.V265= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs756721375, COSV100933341, COSV63741024; called by muse, mutect2, varscan2
- MUC16 | c.40467C>T p.N13489= | Silent (SNP) | VAF 143/730 reads (20%) | catalogued as rs1184375183, COSV101109908, COSV66693138; called by muse, mutect2, varscan2
- NRK | c.3507T>A p.A1169= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as COSV99687853; called by muse, mutect2, varscan2
- NRXN1 | c.753C>A p.R251= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs770481343, COSV68017007, COSV68029526; ClinVar: likely benign; called by mutect2, varscan2
- OR10Q1 | c.147C>A p.I49= | Silent (SNP) | VAF 114/551 reads (21%) | catalogued as COSV100372284; called by muse, mutect2, varscan2
- OR11H1 | c.447C>A p.V149= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs1329064460; called by mutect2, varscan2
- OR51Q1 | c.219G>C p.L73= | Silent (SNP) | VAF 78/540 reads (14%) | catalogued as COSV100332939; called by muse, mutect2, varscan2
- OR5F1 | c.648C>A p.S216= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV99558647; called by muse, mutect2, varscan2
- PNMA8A | c.93A>T p.P31= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV100562332; called by muse, mutect2, varscan2
- POLE | c.4368A>G p.S1456= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as COSV100266762; called by muse, mutect2, varscan2
- PSG3 | c.1017T>A p.P339= | Silent (SNP) | VAF 160/393 reads (41%) | catalogued as COSV100548985; called by muse, mutect2, varscan2
- RHOT1 | c.1008C>T p.F336= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV100447276; called by muse, mutect2, varscan2
- RNF40 | c.2217C>T p.H739= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- RNF40 | c.2218C>T p.L740= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100222259; called by muse, varscan2
- RPL18A | c.282C>T p.Y94= | Silent (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2
- SCN3A | c.3315T>A p.I1105= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV99327075; called by muse, mutect2, varscan2
- SCN3B | c.204C>G p.G68= | Silent (SNP) | VAF 42/210 reads (20%) | catalogued as COSV100173727, COSV54798179; called by muse, mutect2, varscan2
- SENP7 | c.843C>T p.S281= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV100053193; called by muse, mutect2
- SHOX2 | c.672C>T p.N224= (on ENST00000441443 / NM_006884.3; = p.N248= on NM_003030.4) | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs778141323, COSV101273795; called by muse, mutect2, varscan2
- SIDT1 | c.2331G>A p.E777= | Silent (SNP) | VAF 81/606 reads (13%) | catalogued as rs767609858, COSV53509207; called by muse, mutect2, varscan2
- SLC2A13 | c.591G>A p.A197= | Silent (SNP) | VAF 38/263 reads (14%) | catalogued as rs779427681, COSV99786503; called by muse, mutect2, varscan2
- TAF3 | c.2736T>C p.C912= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100720147; called by muse, mutect2, varscan2
- TAT | c.630T>C p.A210= | Silent (SNP) | VAF 21/212 reads (10%) | catalogued as COSV100587633; called by muse, mutect2
- TCP11 | c.960G>A p.L320= (on ENST00000512012; = p.L258= on NM_018679.5) | Silent (SNP) | VAF 18/110 reads (16%) | called by muse, varscan2
- TENM3 | c.624G>A p.L208= | Silent (SNP) | VAF 55/261 reads (21%) | catalogued as COSV101305123; called by muse, mutect2, varscan2
- TG | c.7155C>T p.D2385= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.87912C>T p.L29304= (on ENST00000591111; = p.L21880= on NM_003319.4) | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.55539C>G p.S18513= (on ENST00000591111; = p.S11089= on NM_003319.4) | Silent (SNP) | VAF 74/386 reads (19%) | catalogued as rs371432689; called by muse, mutect2, varscan2
- TTN | c.23349C>T p.V7783= (on ENST00000591111; = p.V6856= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100613700; called by muse, mutect2, varscan2
- WDR36 | c.1731G>A p.V577= | Silent (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- ZEB1 | c.1101A>C p.S367= | Silent (SNP) | VAF 15/157 reads (10%) | catalogued as COSV100314428, COSV58038675; called by muse, mutect2
- AGAP7P | n.1351G>A | RNA (SNP) | VAF 11/128 reads (9%) | catalogued as rs1554941301; called by muse, mutect2, varscan2
- ARSB | c.1213+23264G>T | Intron (SNP) | VAF 30/324 reads (9%) | catalogued as COSV99364790; called by muse, mutect2
- FGF13 | c.403-32125G>T | Intron (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100264181; called by muse, mutect2, varscan2
- STX2 | c.*69T>C | 3'UTR (SNP) | VAF 22/110 reads (20%) | catalogued as COSV99892873; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2940G>A | Intron (SNP) | VAF 27/265 reads (10%) | catalogued as COSV100314287; called by muse, mutect2, varscan2
- TTN | c.10360+1192A>G | Intron (SNP) | VAF 45/278 reads (16%) | catalogued as COSV100613701; called by muse, mutect2, varscan2
- XIST | n.9628C>G | RNA (SNP) | VAF 20/28 reads (71%) | called by muse, mutect2, varscan2
